Gene-level copy-number profile of tumor specimen ALCH-B40B-TTP1-A from ALCHEMIST case ALCH-B40B, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.8 years (22,567 days).
Specimen ALCH-B40B-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fafc509a-3177-40a9-9667-7f91e0ae6b5c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B40B-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/29b01449-be6d-4591-ba60-aa8d018e9036

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 400; copy number 2: 52,855; copy number 3: 5,128; copy number 4: 4; copy number 5: 1; copy number 6: 3; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:84,638,405–84,881,924, 2 genes, copy number 6: LINC00971, AC117482.1.
- chr15:21,053,004–21,081,447, 2 genes, copy number 6–7: AC037471.1, BCAR1P2.
- chr15:21,148,334–21,152,970, 1 gene, copy number 5: AC126335.2.

Autosomal genes at a single copy (total copy number 1): 400. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
